Somatic mutation profile of tumor specimen TCGA-25-1313-01A (aliquot TCGA-25-1313-01A-01W-0492-08) from TCGA case TCGA-25-1313, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 62.9 years (22,982 days).
Specimen TCGA-25-1313-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 534f5de2-cf70-4993-aa1f-cfbb6424a937.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-25-1313-10A (Blood Derived Normal), aliquot TCGA-25-1313-10A-01W-0492-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2bdb8e9b-e26a-496b-9db7-3858de1c1973

The open-access MAF lists 174 somatic variants for this specimen: 136 protein-altering or splice-affecting, 32 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 109, Silent 32, Nonsense Mutation 9, Frame Shift Del 8, Splice Site 6, Intron 2, In Frame Del 2, 3'Flank 2, Frame Shift Ins 2, 5'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NTRK1 | c.1945C>T p.R649W | Missense Mutation (SNP) | VAF 88/515 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369353892, CM990979, COSV100693131; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AC098582.1 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 26/583 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as COSV99985831; called by muse, mutect2
- ACSL1 | c.1240C>T p.R414W | Missense Mutation (SNP) | VAF 32/558 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as rs755845769, COSV99860839; called by muse, mutect2
- ADAM30 | c.1310C>G p.A437G | Missense Mutation (SNP) | VAF 21/222 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); catalogued as COSV65561745; called by muse, mutect2, varscan2
- ADAMTS12 | c.1482C>G p.N494K | Missense Mutation (SNP) | VAF 153/439 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as COSV61272719, COSV61282847; called by muse, mutect2, varscan2
- ADGRF1 | c.1144C>T p.L382F | Missense Mutation (SNP) | VAF 49/333 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV51946916; called by muse, mutect2, varscan2
- ADRA2B | c.482G>A p.R161H | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.806); catalogued as COSV69788043; called by muse, mutect2, varscan2
- ALDH1A3 | c.1001G>C p.S334T | Missense Mutation (SNP) | VAF 73/400 reads (18%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.993); catalogued as COSV100320585; called by muse, mutect2, varscan2
- AMOTL2 | c.221C>A p.P74H | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51440266; called by muse, mutect2, varscan2
- ANO5 | c.1186T>A p.L396I | Missense Mutation (SNP) | VAF 138/331 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV100202053; called by muse, mutect2, varscan2
- APOLD1 | c.516C>G p.F172L (on ENST00000326765 / NM_001130415.2; = p.F141L on NM_030817.3) | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.76); PolyPhen benign (0.098); catalogued as COSV100458364, COSV58733754; called by muse, mutect2, varscan2
- ARID3C | c.866-1G>C p.X289_splice | Splice Site (SNP) | VAF 8/28 reads (29%) | catalogued as COSV52408413, COSV52409196; called by muse, mutect2, varscan2
- ASF1B | c.388C>T p.P130S | Missense Mutation (SNP) | VAF 302/573 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs187314288, COSV54616680; called by muse, mutect2, varscan2
- ATP8B2 | c.2181C>G p.D727E (on ENST00000672630; = p.D694E on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 92/248 reads (37%) | SIFT tolerated (0.67); PolyPhen benign (0.044); catalogued as COSV100528155; called by muse, mutect2, varscan2
- BIK | c.115C>A p.L39M | Missense Mutation (SNP) | VAF 48/592 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.486); catalogued as COSV99330486; called by muse, mutect2
- CA9 | c.1055G>T p.S352I | Missense Mutation (SNP) | VAF 126/392 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61407196; called by muse, mutect2, varscan2
- CASR | c.1802G>A p.R601H (on ENST00000490131; = p.R678H on NM_000388.4) | Missense Mutation (SNP) | VAF 68/209 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.629); catalogued as rs1278025825, CM165796, COSV56139931, COSV56142619; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDC42BPG | c.2090A>G p.Y697C | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1410241877, COSV61348512; called by muse, mutect2, varscan2
- CELSR2 | c.407C>A p.P136Q | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as COSV54777021; called by muse, mutect2
- CFAP91 | c.620C>T p.A207V | Missense Mutation (SNP) | VAF 42/259 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.061); catalogued as rs1178017595, COSV56343278; called by muse, mutect2, varscan2
- CLNK | c.1066G>A p.V356I | Missense Mutation (SNP) | VAF 13/129 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV99905590; called by muse, mutect2
- COL25A1 | c.1090C>T p.R364W | Missense Mutation (SNP) | VAF 27/203 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs960016417, COSV67651331; called by muse, mutect2, varscan2
- CSRNP3 | c.290G>A p.R97H | Missense Mutation (SNP) | VAF 41/216 reads (19%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.996); catalogued as rs774078840, COSV58783115, COSV58784586; called by muse, mutect2, varscan2
- CTDSP2 | c.160A>G p.S54G | Missense Mutation (SNP) | VAF 14/340 reads (4%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs920674389, COSV101143053; called by muse, mutect2
- DCPS | c.835C>A p.H279N | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55011950; called by muse, mutect2, varscan2
- DHTKD1 | c.542C>G p.A181G | Missense Mutation (SNP) | VAF 62/802 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.287); catalogued as COSV99536762; called by muse, mutect2
- DHX32 | c.1960G>T p.G654C | Missense Mutation (SNP) | VAF 157/1192 reads (13%) | SIFT tolerated (0.82); PolyPhen benign (0.003); catalogued as COSV52942454; called by muse, mutect2, varscan2
- DMRT3 | c.761T>A p.V254E | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51907008; called by muse, mutect2, varscan2
- DMXL1 | c.5855G>A p.W1952* | Nonsense Mutation (SNP) | VAF 8/138 reads (6%) | catalogued as COSV100224540; called by muse, mutect2
- DPYSL5 | c.600+1G>A p.X200_splice | Splice Site (SNP) | VAF 24/67 reads (36%) | catalogued as COSV56514783; called by muse, mutect2, varscan2
- DYRK1A | c.1672-1G>C p.X558_splice | Splice Site (SNP) | VAF 22/466 reads (5%) | catalogued as COSV100118015, COSV100118155; called by muse, mutect2
- EPHB1 | c.1634C>G p.S545W | Missense Mutation (SNP) | VAF 48/613 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.548); catalogued as COSV67666777; called by muse, mutect2
- ERRFI1 | c.971C>G p.P324R | Missense Mutation (SNP) | VAF 374/1191 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101088205; called by muse, mutect2, varscan2
- EVL | c.985A>T p.S329C (on ENST00000402714 / NM_001330221.2; = p.S331C on NM_016337.3) | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs776649695, COSV67376642; called by muse, mutect2, varscan2
- F8 | c.259T>A p.W87R | Missense Mutation (SNP) | VAF 82/256 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64276986; called by muse, mutect2, varscan2
- FAM111B | c.1685G>A p.W562* | Nonsense Mutation (SNP) | VAF 110/355 reads (31%) | catalogued as COSV59113003; called by muse, mutect2, varscan2
- FLAD1 | c.1306A>C p.I436L | Missense Mutation (SNP) | VAF 458/1715 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.343); catalogued as COSV52698652; called by muse, mutect2, varscan2
- FLG2 | c.6586C>A p.H2196N | Missense Mutation (SNP) | VAF 506/1643 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.908); catalogued as COSV66171292; called by muse, varscan2
- FOXB1 | c.514A>T p.I172F | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV68526313; called by muse, mutect2, varscan2
- FPR3 | c.503G>T p.S168I | Missense Mutation (SNP) | VAF 562/4710 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.035); catalogued as COSV59331246; called by muse, mutect2, varscan2
- FRMPD1 | c.925G>C p.A309P | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66701826; called by muse, mutect2, varscan2
- G2E3 | c.1603G>A p.D535N | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52842037; called by muse, mutect2, varscan2
- GAB4 | c.1402T>A p.S468T | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.956); catalogued as COSV68754700, COSV68754723; called by muse, mutect2, varscan2
- GON4L | c.3709G>A p.D1237N | Missense Mutation (SNP) | VAF 63/541 reads (12%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.003); catalogued as COSV55199795; called by muse, mutect2, varscan2
- GRAMD1C | c.973C>G p.L325V | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.081); catalogued as rs199895173, COSV63983735; called by muse, mutect2, varscan2
- H1-2 | c.327G>C p.K109N | Missense Mutation (SNP) | VAF 22/216 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59190495, COSV59190892; called by muse, mutect2, varscan2
- H3C3 | c.7C>G p.R3G | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.015); catalogued as COSV63550608; called by muse, mutect2, varscan2
- HPN | c.996C>G p.I332M | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52885140; called by muse, mutect2, varscan2
- IL4R | c.1060G>T p.E354* | Nonsense Mutation (SNP) | VAF 9/160 reads (6%) | catalogued as COSV50166646; called by muse, mutect2
- IRAK4 | c.157A>G p.I53V | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as COSV71210811; called by muse, mutect2, varscan2
- ITGA3 | c.226dup p.R76Pfs*27 | Frame Shift Ins (INS) | VAF 5/42 reads (12%) | catalogued as rs752236693; called by pindel, varscan2
- ITPK1 | c.668C>T p.S223L | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.083); catalogued as COSV50898313; called by muse, mutect2, varscan2
- KANSL1L | c.2285G>A p.R762Q | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.99); catalogued as rs779533363, COSV55995172, COSV99910618; called by muse, mutect2, varscan2
- KIAA0100 | c.2410A>T p.N804Y | Missense Mutation (SNP) | VAF 62/115 reads (54%) | SIFT deleterious (0.04); PolyPhen benign (0.135); catalogued as COSV66495453; called by muse, mutect2, varscan2
- KIFC3 | c.1352G>A p.R451H | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs980456107, COSV65552264; called by muse, mutect2, varscan2
- KRTAP4-12 | c.244G>A p.V82M | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.313); catalogued as rs1555584236, COSV101224247; called by muse, varscan2
- LAPTM4A | c.133A>C p.I45L | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV51533330; called by muse, mutect2, varscan2
- LYST | c.1781C>A p.P594H | Missense Mutation (SNP) | VAF 95/491 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67711311; called by muse, mutect2, varscan2
- MDN1 | c.12567G>C p.W4189C | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65527124; called by muse, mutect2, varscan2
- MGAM | c.842A>G p.K281R | Missense Mutation (SNP) | VAF 274/1916 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV71885846; called by muse, mutect2, varscan2
- MIGA1 | c.619G>T p.E207* | Nonsense Mutation (SNP) | VAF 10/171 reads (6%) | catalogued as COSV100889794; called by muse, mutect2
- MORC3 | c.1597C>G p.Q533E | Missense Mutation (SNP) | VAF 27/144 reads (19%) | SIFT tolerated (0.68); PolyPhen benign (0.012); catalogued as COSV68203702; called by muse, mutect2, varscan2
- MRPS18B | c.394G>T p.G132C | Missense Mutation (SNP) | VAF 96/330 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52541589, COSV52542268; called by muse, mutect2, varscan2
- MS4A5 | c.382G>A p.A128T | Missense Mutation (SNP) | VAF 33/131 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55741863; called by muse, mutect2, varscan2
- NBEAL1 | c.4113G>C p.L1371F | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.028); catalogued as rs756584710, COSV71375173; called by muse, mutect2, varscan2
- NCOA3 | c.47G>A p.R16Q | Missense Mutation (SNP) | VAF 12/357 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.451); catalogued as rs1348905384, COSV59066432; called by muse, mutect2
- NUMB | c.1567A>G p.N523D (on ENST00000355058; = p.N512D on NM_003744.5) | Missense Mutation (SNP) | VAF 108/252 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as COSV99390153; called by mutect2, varscan2
- NUMB | c.619G>T p.E207* (on ENST00000355058; = p.E196* on NM_003744.5) | Nonsense Mutation (SNP) | VAF 44/1546 reads (3%) | catalogued as COSV100679942; called by muse, mutect2
- OGA | c.2453A>T p.E818V | Missense Mutation (SNP) | VAF 23/134 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.576); catalogued as COSV63382664; called by muse, varscan2
- OGDH | c.1873C>T p.P625S | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1408474732, COSV99759342; called by muse, mutect2, varscan2
- OR2T12 | c.443T>A p.L148H | Missense Mutation (SNP) | VAF 58/319 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100528016, COSV58778872; called by muse, mutect2, varscan2
- PAK3 | c.1570T>C p.S524P (on ENST00000262836 / NM_001324328.2; = p.S509P on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 144/479 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV53278345; called by muse, mutect2, varscan2
- PAPPA | c.4627C>G p.L1543V | Missense Mutation (SNP) | VAF 385/1872 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV60289146; called by muse, mutect2, varscan2
- PAX6 | c.527G>T p.G176V | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.011); catalogued as COSV53794963; called by muse, mutect2, varscan2
- PDE4A | c.2363G>A p.S788N (on ENST00000380702 / NM_001111307.2; = p.S549N on NM_006202.3) | Missense Mutation (SNP) | VAF 80/250 reads (32%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.107); catalogued as COSV99534818; called by muse, varscan2
- PI4KA | c.4751G>A p.S1584N | Missense Mutation (SNP) | VAF 40/202 reads (20%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.516); catalogued as rs150837939; called by muse, mutect2, varscan2
- PLA2G4F | c.924C>A p.S308R | Missense Mutation (SNP) | VAF 35/61 reads (57%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as COSV51828596; called by muse, mutect2, varscan2
- PLCB1 | c.1615G>A p.E539K | Missense Mutation (SNP) | VAF 25/240 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.64); catalogued as COSV62061796; called by muse, mutect2, varscan2
- PLD5 | c.1282G>C p.E428Q (on ENST00000442594; = p.E366Q on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/161 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.342); catalogued as COSV59160776; called by muse, mutect2, varscan2
- PLEKHG4 | c.32C>T p.S11F | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.641); catalogued as rs1255719107, COSV64613633; called by muse, mutect2, varscan2
- POU3F4 | c.80A>T p.Q27L | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.276); catalogued as COSV100937302; called by muse, mutect2
- PRDM14 | c.982G>A p.V328I | Missense Mutation (SNP) | VAF 23/150 reads (15%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.998); catalogued as rs1432537822, COSV52572840; called by muse, mutect2
- PRKG1 | c.841-2A>T p.X281_splice | Splice Site (SNP) | VAF 8/48 reads (17%) | catalogued as COSV64775166; called by muse, mutect2
- PRUNE2 | c.2377G>A p.A793T | Missense Mutation (SNP) | VAF 128/961 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.018); catalogued as rs1376046356, COSV100944952; called by muse, mutect2, varscan2
- PTGFRN | c.1785C>A p.D595E | Missense Mutation (SNP) | VAF 22/378 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV101277423; called by muse, mutect2
- RAB36 | c.270G>A p.W90* | Nonsense Mutation (SNP) | VAF 37/103 reads (36%) | catalogued as COSV54075972; called by muse, mutect2, varscan2
- RGS22 | c.1221T>A p.Y407* | Nonsense Mutation (SNP) | VAF 52/209 reads (25%) | catalogued as COSV62665450; called by muse, mutect2, varscan2
- RSPH10B | c.1649T>G p.M550R | Missense Mutation (SNP) | VAF 64/294 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.462); catalogued as COSV61755855; called by muse, mutect2, varscan2
- S1PR1 | c.132C>A p.S44R | Missense Mutation (SNP) | VAF 44/249 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV59514019; called by muse, mutect2, varscan2
- SERPINE1 | c.103G>T p.A35S | Missense Mutation (SNP) | VAF 44/622 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0.035); catalogued as COSV99776797; called by muse, mutect2
- SF3B2 | c.1675C>T p.P559S | Missense Mutation (SNP) | VAF 83/247 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV59429532; called by muse, mutect2, varscan2
- SH3PXD2B | c.2012G>C p.R671T | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV61128759; called by muse, mutect2, varscan2
- SLIT2 | c.160C>T p.P54S | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.13); PolyPhen probably damaging (1); catalogued as COSV99885976; called by muse, mutect2
- SNTG1 | c.557T>A p.L186* | Nonsense Mutation (SNP) | VAF 50/294 reads (17%) | catalogued as COSV52461387; called by muse, mutect2, varscan2
- SOCS6 | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 68/212 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.778); catalogued as rs777820754, COSV67546888; called by muse, mutect2, varscan2
- STPG1 | c.566C>T p.P189L (on ENST00000337248 / NM_001199013.2; = p.P142L on NM_178122.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 170/859 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as COSV50222122; called by muse, mutect2, varscan2
- SVEP1 | c.1119T>G p.C373W | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57043569; called by muse, mutect2, varscan2
- SYTL2 | c.898G>C p.V300L | Missense Mutation (SNP) | VAF 55/266 reads (21%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV100314651; called by muse, mutect2, varscan2
- TBX5 | c.1123C>T p.R375W | Missense Mutation (SNP) | VAF 286/553 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs377532269; ClinVar: benign; called by muse, mutect2, varscan2
- TCTE1 | c.425G>A p.C142Y | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV65256071; called by muse, mutect2
- THAP8 | c.541C>A p.Q181K | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as COSV53078821; called by muse, varscan2
- TINAG | c.895C>T p.R299C | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as rs376779713, COSV52513828; called by muse, mutect2
- TKTL1 | c.1130G>C p.G377A | Missense Mutation (SNP) | VAF 186/1095 reads (17%) | SIFT tolerated (0.93); PolyPhen benign (0.371); catalogued as rs201125069, COSV54214103; called by muse, varscan2
- TMPRSS15 | c.1061G>T p.C354F | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53045331; called by muse, mutect2, varscan2
- TMTC4 | c.1774C>T p.R592C (on ENST00000376234 / NM_001350577.2; = p.R611C on NM_032813.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/133 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as rs1430665035, COSV60891405; called by muse, mutect2
- TNC | c.4615G>T p.D1539Y | Missense Mutation (SNP) | VAF 157/487 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs770213784, COSV100406091, COSV60783802; called by muse, mutect2, varscan2
- TP53 | c.434T>G p.L145R | Missense Mutation (SNP) | VAF 113/185 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV52676080, COSV52724970, COSV52728973; called by muse, mutect2, varscan2
- TRAPPC8 | c.3304C>G p.L1102V | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.056); catalogued as COSV51975340; called by muse, mutect2, varscan2
- TRIM67 | c.1839C>A p.D613E | Missense Mutation (SNP) | VAF 31/477 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as COSV100792181; called by muse, mutect2
- UBAC2 | c.409C>G p.L137V (on ENST00000403766 / NM_001144072.2; = p.L102V on NM_177967.4) | Missense Mutation (SNP) | VAF 449/881 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.631); catalogued as COSV63120197; called by muse, mutect2, varscan2
- UNC45A | c.1978A>G p.T660A | Missense Mutation (SNP) | VAF 19/30 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.401); catalogued as COSV67817230; called by muse, mutect2, varscan2
- URB2 | c.2863G>A p.G955R | Missense Mutation (SNP) | VAF 60/527 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1397869452, COSV51016019; called by muse, mutect2, varscan2
- USP34 | c.3814C>T p.P1272S | Missense Mutation (SNP) | VAF 133/415 reads (32%) | SIFT tolerated (0.92); PolyPhen benign (0.269); catalogued as COSV68404353; called by muse, mutect2, varscan2
- VSNL1 | c.42G>T p.E14D | Missense Mutation (SNP) | VAF 261/1563 reads (17%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV54602128; called by muse, mutect2, varscan2
- ZAN | c.6367G>T p.E2123* | Nonsense Mutation (SNP) | VAF 6/27 reads (22%) | catalogued as COSV61812947; called by muse, mutect2, varscan2
- ZFP1 | c.850A>T p.T284S | Missense Mutation (SNP) | VAF 41/128 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.097); catalogued as COSV60033858; called by muse, mutect2, varscan2
- ZKSCAN4 | c.1568G>C p.G523A | Missense Mutation (SNP) | VAF 62/697 reads (9%) | SIFT tolerated (0.85); PolyPhen benign (0.154); catalogued as COSV66023849; called by muse, mutect2
- ZNF132 | c.2025A>C p.K675N | Missense Mutation (SNP) | VAF 77/555 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.054); catalogued as COSV54235752; called by muse, mutect2, varscan2
- ZNF25 | c.788G>C p.C263S | Missense Mutation (SNP) | VAF 99/363 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV56923613; called by muse, mutect2, varscan2
- ZNF292 | c.3791C>T p.P1264L | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV60544194; called by muse, mutect2, varscan2
- ZNF304 | c.1426G>A p.E476K | Missense Mutation (SNP) | VAF 33/464 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as COSV99988758; called by muse, mutect2
- ZNF577 | c.841C>G p.Q281E | Missense Mutation (SNP) | VAF 46/313 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.317); catalogued as COSV100031190; called by muse, mutect2, varscan2
- CD163L1 | c.3202_3221del p.D1069Kfs*27 | Frame Shift Del (DEL) | VAF 105/330 reads (32%) | called by mutect2, pindel, varscan2
- CPT1B | c.609del p.M204Wfs*31 | Frame Shift Del (DEL) | VAF 18/101 reads (18%) | called by mutect2, pindel, varscan2
- DNAH6 | c.1471_1481del p.V491Kfs*13 | Frame Shift Del (DEL) | VAF 4/79 reads (5%) | called by mutect2, pindel*
- FPR3 | c.358_375del p.A120_I125del | In Frame Del (DEL) | VAF 296/2284 reads (13%) | called by mutect2, pindel
- GSS | c.1101_1111del p.E368* | Frame Shift Del (DEL) | VAF 28/314 reads (9%) | called by mutect2, pindel
- KCNA4 | c.969del p.C325Afs*18 | Frame Shift Del (DEL) | VAF 20/182 reads (11%) | called by mutect2, varscan2
- KLK9 | c.604-8_604-1delinsC p.X202_splice | Splice Site (DEL) | VAF 14/73 reads (19%) | called by pindel, varscan2*
- MAPKBP1 | c.2208G>T p.M736I (on ENST00000456763 / NM_001128608.2; = p.M730I on NM_014994.3) | Missense Mutation (SNP) | VAF 27/183 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.093); called by muse, mutect2
- RPGRIP1 | c.2741_2751del p.K914Ifs*16 | Frame Shift Del (DEL) | VAF 91/708 reads (13%) | called by mutect2, pindel, varscan2
- SRPX | c.1204_1211+11del p.X402_splice | Splice Site (DEL) | VAF 45/257 reads (18%) | called by mutect2, pindel, varscan2
- TMCC1 | c.1712_1727del p.V571Gfs*32 (on ENST00000393238 / NM_001349268.2; = p.V247Gfs*32 on NM_015008.5 and 6 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 26/169 reads (15%) | called by pindel, varscan2
- TOP2A | c.592_593del p.M198Gfs*5 | Frame Shift Del (DEL) | VAF 2338/3194 reads (73%) | called by pindel, varscan2
- TRPV4 | c.432dup p.I145Hfs*12 | Frame Shift Ins (INS) | VAF 4/23 reads (17%) | called by pindel, varscan2
- TSC22D2 | c.1886_1906del p.Q629_S635del | In Frame Del (DEL) | VAF 6/31 reads (19%) | called by mutect2, pindel, varscan2
- ADAM22 | c.981T>C p.V327= | Silent (SNP) | VAF 81/443 reads (18%) | catalogued as rs774875141, COSV55985301; called by muse, mutect2, varscan2
- ARHGAP31 | c.928C>T p.L310= | Silent (SNP) | VAF 29/245 reads (12%) | catalogued as COSV51796970; called by muse, mutect2, varscan2
- CIT | c.5613G>A p.P1871= | Silent (SNP) | VAF 110/452 reads (24%) | catalogued as rs373669183, COSV55864388; called by muse, mutect2, varscan2
- DYNC2H1 | c.8052A>G p.G2684= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as COSV62101964; called by muse, mutect2, varscan2
- EGFL7 | c.810G>A p.K270= | Silent (SNP) | VAF 6/9 reads (67%) | catalogued as COSV58248327; called by muse, mutect2, varscan2
- EGR2 | c.657C>G p.L219= | Silent (SNP) | VAF 26/104 reads (25%) | catalogued as COSV54348261; called by muse, mutect2, varscan2
- FAM189B | c.1647G>C p.R549= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as COSV59170610; called by muse, mutect2, varscan2
- FAT2 | c.8853C>A p.P2951= | Silent (SNP) | VAF 33/129 reads (26%) | catalogued as COSV55826075; called by muse, mutect2, varscan2
- GANAB | c.1479G>C p.R493= | Silent (SNP) | VAF 49/327 reads (15%) | catalogued as COSV100648224, COSV60467371; called by muse, mutect2, varscan2
- GLP2R | c.1302G>A p.L434= | Silent (SNP) | VAF 58/543 reads (11%) | catalogued as COSV52327829; called by muse, mutect2, varscan2
- GUCA1A | c.6C>G p.G2= | Silent (SNP) | VAF 12/140 reads (9%) | catalogued as COSV99274196; called by muse, mutect2
- ITGB3 | c.1530C>T p.D510= | Silent (SNP) | VAF 64/428 reads (15%) | catalogued as rs144502977, COSV71384862; called by muse, mutect2, varscan2
- KCNB2 | c.1572G>T p.L524= | Silent (SNP) | VAF 296/597 reads (50%) | catalogued as COSV73051808; called by muse, mutect2, varscan2
- MCM2 | c.789C>A p.A263= | Silent (SNP) | VAF 16/81 reads (20%) | catalogued as COSV54036012; called by muse, mutect2, varscan2
- MIA3 | c.5649C>T p.G1883= | Silent (SNP) | VAF 85/572 reads (15%) | catalogued as COSV60516057; called by muse, mutect2, varscan2
- MICAL3 | c.42C>T p.V14= | Silent (SNP) | VAF 63/1043 reads (6%) | catalogued as rs769647662, COSV99262514; called by muse, mutect2
- MOSPD3 | c.705C>G p.T235= | Silent (SNP) | VAF 12/68 reads (18%) | catalogued as COSV56158665; called by muse, mutect2, varscan2
- MUC3A | c.7956C>G p.L2652= | Silent (SNP) | VAF 129/863 reads (15%) | catalogued as COSV100114011, COSV100115086; called by muse, mutect2
- NCAPD2 | c.2448C>T p.C816= | Silent (SNP) | VAF 67/162 reads (41%) | catalogued as COSV59697861; called by muse, mutect2, varscan2
- NUAK2 | c.1122C>G p.L374= | Silent (SNP) | VAF 21/89 reads (24%) | catalogued as COSV65682278; called by muse, mutect2, varscan2
- OR5T1 | c.966C>T p.F322= | Silent (SNP) | VAF 17/127 reads (13%) | catalogued as COSV57302038; called by muse, mutect2, varscan2
- PCDHB2 | c.33G>T p.P11= | Silent (SNP) | VAF 17/143 reads (12%) | catalogued as COSV52030974, COSV52035730; called by muse, mutect2, varscan2
- PIK3C2G | c.3174C>T p.Y1058= (on ENST00000676171; = p.Y1017= on NM_004570.5) | Silent (SNP) | VAF 31/232 reads (13%) | catalogued as COSV56823776; called by muse, mutect2, varscan2
- PPP6C | c.447C>T p.L149= | Silent (SNP) | VAF 95/212 reads (45%) | catalogued as rs142534549; called by muse, mutect2, varscan2
- RET | c.1311C>T p.N437= | Silent (SNP) | VAF 11/98 reads (11%) | catalogued as rs1190189942, COSV60695896; ClinVar: likely benign; called by muse, mutect2, varscan2
- RGS20 | c.1158T>C p.I386= (on ENST00000297313 / NM_170587.4; = p.I239= on NM_003702.4) | Silent (SNP) | VAF 286/533 reads (54%) | catalogued as COSV52020617; called by muse, mutect2, varscan2
- RITA1 | c.633T>A p.G211= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV100232463; called by muse, varscan2
- SLC1A7 | c.1347C>G p.A449= | Silent (SNP) | VAF 29/111 reads (26%) | catalogued as COSV57015942; called by muse, mutect2, varscan2
- SLIT2 | c.162C>T p.P54= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as COSV99885979; called by muse, mutect2
- SPTBN4 | c.705C>T p.S235= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as COSV58956176; called by muse, mutect2, varscan2
- TSPOAP1 | c.5304C>G p.S1768= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as COSV52114681; called by muse, mutect2, varscan2
- TTN | c.38313A>G p.T12771= (on ENST00000591111; = p.T5347= on NM_003319.4) | Silent (SNP) | VAF 117/1025 reads (11%) | catalogued as COSV60237688; called by muse, varscan2
- DIO2 | c.223-2355G>A | Intron (SNP) | VAF 39/344 reads (11%) | called by muse, mutect2, varscan2
- NDUFS4 | c.-1G>A | 5'UTR (SNP) | VAF 154/518 reads (30%) | catalogued as COSV99692312; called by muse, mutect2
- RNF217-AS1 | n.1669A>G | RNA (SNP) | VAF 111/432 reads (26%) | catalogued as rs970223431; called by muse, mutect2, varscan2
- SNORD52 | chr6:31837406 G>C | 3'Flank (SNP) | VAF 111/444 reads (25%) | catalogued as rs949116913, COSV100794746; called by muse, mutect2, varscan2
- ST8SIA2 | chr15:92472250 T>A | 3'Flank (SNP) | VAF 11/158 reads (7%) | called by muse, mutect2
- TTN | c.10360+5313T>A | Intron (SNP) | VAF 231/549 reads (42%) | catalogued as COSV60237707; called by muse, mutect2, varscan2
